Gene-level copy-number profile of tumor specimen MP2PRT-PAUGMT-TTP1-A from MP2PRT case MP2PRT-PAUGMT, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 13.1 years (4,775 days).
Specimen MP2PRT-PAUGMT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 594dce46-1ff7-40a4-ad47-d891429f86f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUGMT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/3891c705-09bf-48cb-9a1a-f2e67893e569

Most common (modal) total copy number across autosomal genes: 0 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 26,541; copy number 1: 69; copy number 2: 22; copy number 3: 19,205; copy number 4: 3; copy number 5: 99; copy number 6: 12,838; copy number 7: 126; copy number 8: 10.

Caution: the most common total copy number in this file is 0 (23,734 autosomal genes at 0 copies), which is not a plausible tumor genome; the fit is treated as unreliable and no deletion or amplification regions are listed.

Homozygous deletions (total copy number 0; autosomes only): 23,734 genes in 14 contiguous regions (regions not listed; see the caution above).

Amplified relative to the modal value (total copy number ≥ 1, i.e. more than twice the modal value of 0; autosomes only): 32,323 genes in 18 contiguous regions (regions not listed; see the caution above).

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
